CGCI case BLGSP-71-32-00699 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/a441e2a2-1dcd-4d83-80f1-ae827704bc4e

Demographics
Sex at birth: female; Age at index: 27 years.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 27.2 years (9,947 days); Year of diagnosis: 2001; Max tumor bulk site: Small intestine.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-32-00699-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-32-00699-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 50; Percent neutrophil infiltration: 10.
  Slide BLGSP-71-32-00699-01A-01-S1-HE: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 50; Percent neutrophil infiltration: 10.
- Sample BLGSP-71-32-00699-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-32-00699-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-32-00699-11A-01-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide BLGSP-71-32-00699-11A-01-S2-HE: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Lost to follow-up: Yes.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology.
